Gene-level copy-number profile of tumor specimen ALCH-B2W1-TTP1-A from ALCHEMIST case ALCH-B2W1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.4 years (26,091 days).
Specimen ALCH-B2W1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a312771e-d4d8-4e0e-834b-26d1d2ecc4fa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2W1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/4c91c72c-c7fc-49b0-8c5e-606895078ece

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 4,814; copy number 2: 49,456; copy number 3: 3,793; copy number 4: 322; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,849,674–120,914,238, 4 genes (within-gene range 0–2): AC253572.1, RNVU1-19, PPIAL4A, AC241377.3.
- chr9:137,007,234–137,046,179, 5 genes: ABCA2, C9orf139, FUT7, AL807752.6, NPDC1.
- chr12:122,834,453–122,862,961, 1 gene: HIP1R.
- chr16:15,125,242–15,154,564, 3 genes (within-gene range 0–2): PKD1P6, MIR6511B2, Y_RNA.
- chr22:50,170,731–50,180,295, 1 gene: PANX2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:12,999,676–13,016,692, 1 gene, copy number 5: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 4,813. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
